Somatic mutation profile of tumor specimen 0DNCOL from CCDI case PBCBJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sertoli-Leydig cell tumor, intermediate differentiation, with heterologous elements; Tissue or organ of origin: Ovary; Age at diagnosis: 17.5 years (6,392 days).
Specimen 0DNCOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59a8663b-e3ee-498e-81d1-b1b2999d828b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCH4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c037a68-5585-4fd1-964d-b2453d8f1b25

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 5, Silent 3, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 317/680 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- HOOK2 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.342); catalogued as rs752500888, COSV53402086; called by muse, mutect2, varscan2
- JAK3 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs587778416; ClinVar: not provided; called by muse, mutect2, varscan2
- OR9A2 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 131/351 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100628159; called by muse, mutect2, varscan2
- PABPC5 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 176/520 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409179532; called by muse, mutect2, varscan2
- TLN2 | c.2039A>G p.N680S | Missense Mutation (SNP) | VAF 186/439 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs139051192; called by muse, mutect2, varscan2
- CLCN4 | c.1406T>A p.F469Y | Missense Mutation (SNP) | VAF 23/492 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.439); called by muse, mutect2
- DICER1 | c.3270-2_3279del p.X1090_splice | Splice Site (DEL) | VAF 171/569 reads (30%) | called by mutect2, varscan2
- MSANTD2 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, varscan2
- PPP2CB | c.808G>T p.G270W | Missense Mutation (SNP) | VAF 58/936 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PPP2CB | c.807T>G p.C269W | Missense Mutation (SNP) | VAF 60/929 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TLK2 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 374/880 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF843 | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2
- KCNA3 | c.69T>C p.P23= | Silent (SNP) | VAF 44/131 reads (34%) | called by muse, mutect2, varscan2
- NLRP12 | c.831G>A p.A277= | Silent (SNP) | VAF 74/169 reads (44%) | catalogued as rs371391087; called by muse, mutect2, varscan2
- TMPRSS4 | c.1032G>C p.L344= | Silent (SNP) | VAF 101/250 reads (40%) | called by muse, mutect2, varscan2
- COX10 | c.*14C>T | 3'UTR (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- CXCR6 | c.-21-43C>T | Intron (SNP) | VAF 12/218 reads (6%) | catalogued as rs1363076618; called by muse, mutect2
- GPM6B | c.61+9139C>A | Intron (SNP) | VAF 225/537 reads (42%) | called by muse, mutect2, varscan2
- ITGA4 | c.1154-57G>A | Intron (SNP) | VAF 97/192 reads (51%) | catalogued as rs1366267869; called by muse, mutect2, varscan2
- TEKT2 | c.1080-54G>T | Intron (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- ZNF45 | c.16-38T>G | Intron (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
